Somatic mutation profile of tumor specimen C3L-04354-02 (aliquot CPT0243090006) from CPTAC case C3L-04354, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 60.3 years (22,041 days).
Specimen C3L-04354-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6344be5-e597-4001-8e00-16c918efae1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04354-32 (Blood Derived Normal), aliquot CPT0243240002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f65fbf8c-d4db-434a-8b0a-c3a265cd53c4

The open-access MAF lists 221 somatic variants for this specimen: 151 protein-altering or splice-affecting, 43 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 134, Silent 43, Intron 9, Frame Shift Del 6, Nonsense Mutation 6, 5'UTR 6, 5'Flank 4, RNA 3, 3'Flank 3, Splice Site 2, 3'UTR 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.725G>T p.C242F | Missense Mutation (SNP) | VAF 158/402 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912655, CM910618, COSV52661189, COSV52677418, COSV52689710; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.8779G>T p.V2927F | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV67984390; called by muse, mutect2, varscan2
- ATP13A1 | c.3566G>A p.R1189H | Missense Mutation (SNP) | VAF 66/351 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs749770133; called by muse, mutect2, varscan2
- BTN2A2 | c.139G>A p.V47M | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs755187913, COSV61857796; called by muse, mutect2
- CCDC141 | c.3375G>C p.K1125N | Missense Mutation (SNP) | VAF 52/312 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV55379682; called by muse, mutect2, varscan2
- CDH6 | c.1138C>A p.P380T | Missense Mutation (SNP) | VAF 63/478 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54065119; called by muse, mutect2, varscan2
- CEACAM4 | c.253G>C p.D85H | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as COSV55732473, COSV55733056; called by muse, mutect2, varscan2
- DNAH11 | c.8228C>T p.A2743V | Missense Mutation (SNP) | VAF 97/316 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.087); catalogued as rs755229531; called by muse, mutect2, varscan2
- DNAH8 | c.2548C>T p.L850F | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.179); catalogued as rs750421296; called by muse, mutect2, varscan2
- DROSHA | c.1478G>T p.C493F | Missense Mutation (SNP) | VAF 54/434 reads (12%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.51); catalogued as rs1442636699; called by muse, mutect2, varscan2
- FMN2 | c.4858G>A p.A1620T | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60430401; called by muse, mutect2, varscan2
- FNDC1 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 101/491 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.067); catalogued as rs377525008; called by muse, mutect2, varscan2
- GABRG1 | c.1003C>A p.L335I | Missense Mutation (SNP) | VAF 39/205 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54959110; called by muse, mutect2, varscan2
- GALNT9 | c.1080G>A p.V360= | Splice Region (SNP) | VAF 94/458 reads (21%) | catalogued as rs1306516838; called by muse, mutect2, varscan2
- IGKV2D-29 | c.136A>T p.S46C | Missense Mutation (SNP) | VAF 72/268 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV101534401, COSV72391453; called by muse, mutect2, varscan2
- INHBB | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 64/367 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371205927; called by muse, mutect2, varscan2
- INPP4A | c.2278G>A p.V760I (on ENST00000074304 / NM_001134224.1; = p.V721I on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.029); catalogued as rs984538193; called by muse, mutect2, varscan2
- ITGA11 | c.2494G>C p.E832Q | Missense Mutation (SNP) | VAF 93/482 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.511); catalogued as COSV59880903; called by muse, mutect2, varscan2
- ITGAL | c.116C>A p.P39Q | Missense Mutation (SNP) | VAF 45/231 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs1264371238; called by muse, mutect2, varscan2
- KDSR | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (1); PolyPhen possibly damaging (0.611); catalogued as rs778337145; called by muse, varscan2
- KHDC4 | c.12del p.S5Afs*72 | Frame Shift Del (DEL) | VAF 47/269 reads (17%) | catalogued as COSV64165965; called by mutect2, pindel, varscan2
- KRT74 | c.377A>G p.N126S | Missense Mutation (SNP) | VAF 84/344 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as COSV59774405; called by muse, mutect2, varscan2
- LYG1 | c.262G>A p.G88S | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as rs769781137; called by muse, mutect2, varscan2
- MAP4K1 | c.2213C>G p.P738R | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV101204171, COSV101204267; called by muse, mutect2, varscan2
- MMRN1 | c.2734C>T p.H912Y | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV53336009; called by muse, mutect2, varscan2
- MROH2B | c.1719G>A p.M573I | Missense Mutation (SNP) | VAF 108/280 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs781659189; called by muse, mutect2, varscan2
- MYO18A | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 60/284 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.732); catalogued as rs375367286; called by muse, mutect2, varscan2
- MYO3A | c.4381G>T p.G1461C | Missense Mutation (SNP) | VAF 82/473 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.554); catalogued as COSV56348969; called by muse, mutect2, varscan2
- NRAS | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 80/432 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs758669528; called by muse, mutect2, varscan2
- OR13F1 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 53/348 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as rs774810702, COSV58250823; called by muse, mutect2, varscan2
- OR2T4 | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 119/673 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as rs774696415; called by muse, mutect2, varscan2
- PCDHA8 | c.499G>A p.V167M | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.135); catalogued as COSV65337057; called by muse, mutect2, varscan2
- PCLO | c.4100C>T p.S1367F | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs777276751; called by muse, mutect2, varscan2
- PDZK1 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 58/282 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs782449747; called by muse, mutect2, varscan2
- PEG3 | c.3124A>G p.T1042A | Missense Mutation (SNP) | VAF 47/234 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as rs1340002297; called by muse, mutect2, varscan2
- PIP5K1A | c.718C>T p.R240W (on ENST00000368888 / NM_001135638.2; = p.R227W on NM_003557.3) | Missense Mutation (SNP) | VAF 59/236 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs766529574; called by muse, mutect2, varscan2
- PITPNC1 | c.182G>C p.R61P | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100083958; called by muse, mutect2, varscan2
- PLK5 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 77/337 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.648); catalogued as rs577609075, COSV58292413; called by muse, mutect2, varscan2
- PLXNC1 | c.2777G>A p.R926Q | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.034); catalogued as rs753617960; called by muse, varscan2
- POM121L12 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.038); catalogued as rs1481598999; called by muse, mutect2, varscan2
- PPFIA2 | c.1438C>G p.L480V | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.269); catalogued as rs1333769308; called by muse, varscan2
- PPFIA2 | c.1403C>A p.T468K | Missense Mutation (SNP) | VAF 38/213 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61049620; called by muse, varscan2
- PRDM9 | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 116/992 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV57003307; called by muse, mutect2, varscan2
- RASL12 | c.541C>T p.R181* | Nonsense Mutation (SNP) | VAF 49/283 reads (17%) | catalogued as rs751668315; called by muse, mutect2, varscan2
- ROBO2 | c.2240C>T p.T747I | Missense Mutation (SNP) | VAF 68/408 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as rs777781837; called by muse, mutect2, varscan2
- SALL3 | c.1576G>T p.V526L | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs573903216, COSV73306433; called by muse, mutect2, varscan2
- SLC36A2 | c.1015T>C p.Y339H | Missense Mutation (SNP) | VAF 104/390 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV58865419; called by muse, mutect2, varscan2
- SOX11 | c.547G>T p.G183C | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs894770529; called by muse, mutect2, varscan2
- SPEF2 | c.4638G>T p.W1546C | Missense Mutation (SNP) | VAF 54/408 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100288698; called by muse, mutect2, varscan2
- TAF13 | c.83G>C p.R28T | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV58039479; called by muse, mutect2, varscan2
- TCERG1L | c.701G>A p.S234N | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV64046893; called by muse, mutect2, varscan2
- TMEM119 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 45/214 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs572995428, COSV67188317; called by muse, mutect2, varscan2
- TMEM178A | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 55/220 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.067); catalogued as rs1228234322; called by muse, mutect2, varscan2
- TMEM74 | c.316G>T p.E106* | Nonsense Mutation (SNP) | VAF 41/198 reads (21%) | catalogued as COSV99865426; called by muse, mutect2, varscan2
- UNC80 | c.3782T>A p.V1261E | Missense Mutation (SNP) | VAF 86/435 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.447); catalogued as COSV55902063; called by muse, mutect2, varscan2
- UPK1B | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 46/347 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs769296250, COSV51766303; called by muse, mutect2, varscan2
- UXS1 | c.289del p.A97Qfs*8 | Frame Shift Del (DEL) | VAF 23/103 reads (22%) | catalogued as COSV51677553; called by mutect2, pindel*
- ZNF492 | c.182dup p.N61Kfs*12 | Frame Shift Ins (INS) | VAF 12/41 reads (29%) | catalogued as rs754633801; called by mutect2, varscan2
- ZNF780A | c.647C>T p.T216I | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs773823184; called by muse, mutect2, varscan2
- ABCD2 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 64/240 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- AC024598.1 | c.941G>T p.G314V | Missense Mutation (SNP) | VAF 59/293 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- AHSG | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 34/219 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- AJUBA | c.424_431delinsA p.L142Rfs*98 | Frame Shift Del (DEL) | VAF 54/246 reads (22%) | called by pindel, varscan2*
- ALDH18A1 | c.920G>T p.G307V | Missense Mutation (SNP) | VAF 101/488 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGEF17 | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 77/282 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- ATG16L1 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 80/401 reads (20%) | called by muse, mutect2, varscan2
- ATP8B4 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 39/212 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ATRAID | c.722G>C p.G241A (on ENST00000611786; = p.G128A on NM_016085.5) | Missense Mutation (SNP) | VAF 47/282 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C1orf56 | c.710C>A p.A237E | Missense Mutation (SNP) | VAF 65/400 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CACNA1F | c.4241G>A p.S1414N | Missense Mutation (SNP) | VAF 95/274 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- CAMSAP2 | c.1496A>T p.E499V (on ENST00000236925 / NM_001297707.2; = p.E488V on NM_203459.3) | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- CCDC39 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- CFH | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 45/242 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CSMD1 | c.2678G>A p.R893K (on ENST00000520002; = p.R892K on NM_033225.6) | Missense Mutation (SNP) | VAF 80/248 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CTAGE9 | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 129/710 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CUBN | c.116T>C p.L39P | Missense Mutation (SNP) | VAF 83/457 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- CUL2 | c.2131T>C p.F711L | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP39A1 | c.1022C>A p.P341H | Missense Mutation (SNP) | VAF 43/222 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DENND1A | c.2981C>A p.A994D | Missense Mutation (SNP) | VAF 84/393 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- DEPTOR | c.898C>A p.P300T | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DNMT3B | c.2302-2A>G p.X768_splice | Splice Site (SNP) | VAF 62/289 reads (21%) | called by muse, mutect2, varscan2
- EBF2 | c.1033T>A p.Y345N | Missense Mutation (SNP) | VAF 65/212 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ELP1 | c.2107del p.Q703Rfs*14 | Frame Shift Del (DEL) | VAF 123/572 reads (22%) | called by mutect2, pindel, varscan2
- ERICH3 | c.2348A>T p.H783L | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM234B | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FANCM | c.4528A>T p.K1510* | Nonsense Mutation (SNP) | VAF 32/81 reads (40%) | called by muse, mutect2, varscan2
- FGF23 | c.377T>G p.V126G | Missense Mutation (SNP) | VAF 174/792 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- FOXL2 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 106/575 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GABRA4 | c.1121A>G p.E374G | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, varscan2
- GC | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 100/489 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- GRIN3B | c.863dup p.L289Afs*7 | Frame Shift Ins (INS) | VAF 36/185 reads (19%) | called by mutect2, pindel, varscan2
- HBM | c.315C>A p.F105L | Missense Mutation (SNP) | VAF 144/654 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- HERC5 | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HOXB3 | c.240del p.E81Sfs*53 | Frame Shift Del (DEL) | VAF 84/357 reads (24%) | called by mutect2, pindel, varscan2
- HOXD13 | c.20G>C p.W7S | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- IRX6 | c.141_157del p.C48* | Frame Shift Del (DEL) | VAF 72/614 reads (12%) | called by mutect2, pindel
- IRX6 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 72/336 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.056); called by muse, varscan2
- ISL2 | c.380G>T p.G127V | Missense Mutation (SNP) | VAF 81/386 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITK | c.495+2T>A p.X165_splice | Splice Site (SNP) | VAF 91/341 reads (27%) | called by muse, mutect2, varscan2
- JAML | c.675G>C p.R225S (on ENST00000356289 / NM_001098526.2; = p.R215S on NM_153206.3) | Missense Mutation (SNP) | VAF 108/367 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- LDB1 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP2 | c.12922A>G p.T4308A | Missense Mutation (SNP) | VAF 18/439 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2
- LRRC8E | c.2224G>T p.G742C | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- MARCKSL1 | c.406G>T p.D136Y | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- MCOLN3 | c.821T>C p.V274A | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- MORC1 | c.800G>T p.C267F | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.09); called by muse, mutect2
- MYCN | c.1295C>A p.S432Y | Missense Mutation (SNP) | VAF 127/607 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- MYO18B | c.2689A>G p.S897G | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.006); called by muse, mutect2
- NF1 | c.1957A>T p.T653S | Missense Mutation (SNP) | VAF 96/419 reads (23%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NIBAN3 | c.1023C>G p.D341E | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NIPSNAP2 | c.671T>C p.F224S | Missense Mutation (SNP) | VAF 74/425 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5H1 | c.656C>A p.T219K | Missense Mutation (SNP) | VAF 58/355 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- PCDH15 | c.5794C>A p.Q1932K | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- POLG | c.2893T>G p.L965V | Missense Mutation (SNP) | VAF 115/578 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PPM1F | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PUM2 | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.988); called by muse, mutect2
- RAD21L1 | c.1572C>A p.S524R | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- RECQL4 | c.104C>A p.P35Q | Missense Mutation (SNP) | VAF 87/254 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RGPD4 | c.5032G>A p.A1678T | Missense Mutation (SNP) | VAF 113/513 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- RGR | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 142/744 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ROS1 | c.4433A>G p.Y1478C | Missense Mutation (SNP) | VAF 71/368 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- SH3BP5L | c.579G>T p.E193D | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- SIGLEC9 | c.1377C>G p.I459M | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- SLC17A8 | c.1459G>C p.A487P | Missense Mutation (SNP) | VAF 31/247 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC25A36 | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC6A14 | c.1832A>G p.E611G | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- SLC9C2 | c.1801T>G p.F601V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SLITRK3 | c.1487A>T p.Q496L | Missense Mutation (SNP) | VAF 74/445 reads (17%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- SRCAP | c.2756C>A p.P919Q | Missense Mutation (SNP) | VAF 45/231 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- SSTR2 | c.169G>T p.G57W | Missense Mutation (SNP) | VAF 94/490 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SVOP | c.331C>G p.L111V | Missense Mutation (SNP) | VAF 39/212 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- TAF1B | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLN1 | c.1573G>C p.D525H | Missense Mutation (SNP) | VAF 58/236 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- TLN1 | c.1516G>T p.V506L | Missense Mutation (SNP) | VAF 83/320 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.073); called by muse, varscan2
- TMCO6 | c.1013T>C p.V338A | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- TMEM131 | c.3427G>T p.A1143S | Missense Mutation (SNP) | VAF 44/256 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TOR1A | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 97/524 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- TTC29 | c.110A>T p.E37V | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- UBP1 | c.1585G>C p.A529P | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- USP19 | c.2675T>A p.L892Q | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- WDR87 | c.7585C>G p.R2529G | Missense Mutation (SNP) | VAF 54/298 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- XRN1 | c.1679G>A p.W560* | Nonsense Mutation (SNP) | VAF 13/91 reads (14%) | called by muse, mutect2, varscan2
- ZFP82 | c.1099G>C p.E367Q | Missense Mutation (SNP) | VAF 59/316 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- ZFY | c.1962A>T p.K654N | Missense Mutation (SNP) | VAF 103/254 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF224 | c.1810G>T p.G604C | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- ZNF385B | c.1094G>T p.C365F | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF611 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 39/179 reads (22%) | called by muse, mutect2, varscan2
- ZNF716 | c.1438G>T p.A480S | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.311); called by muse, mutect2
- ZNF732 | c.890A>G p.K297R | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- ZNF853 | c.1319A>T p.Y440F | Missense Mutation (SNP) | VAF 102/291 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- ZP4 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADAMTS7 | c.4575C>T p.Y1525= | Silent (SNP) | VAF 39/124 reads (31%) | called by muse, mutect2, varscan2
- ANO5 | c.1365T>C p.R455= | Silent (SNP) | VAF 81/455 reads (18%) | called by muse, mutect2, varscan2
- ASB1 | c.291C>T p.L97= | Silent (SNP) | VAF 63/297 reads (21%) | called by muse, mutect2, varscan2
- ATXN7 | c.1224G>A p.P408= | Silent (SNP) | VAF 33/137 reads (24%) | catalogued as rs752995222, COSV55749344; called by muse, mutect2, varscan2
- BARX1 | c.201G>T p.A67= | Silent (SNP) | VAF 85/252 reads (34%) | called by mutect2, varscan2
- C9orf135 | c.411A>T p.G137= | Silent (SNP) | VAF 73/218 reads (33%) | called by muse, mutect2, varscan2
- CACNA1I | c.4755C>A p.R1585= | Silent (SNP) | VAF 73/197 reads (37%) | catalogued as COSV100360661; called by muse, mutect2, varscan2
- CCDC50 | c.108A>G p.Q36= | Silent (SNP) | VAF 74/469 reads (16%) | called by muse, mutect2, varscan2
- CD160 | c.489A>C p.L163= | Silent (SNP) | VAF 78/375 reads (21%) | called by muse, mutect2, varscan2
- CDH23 | c.8740C>T p.L2914= | Silent (SNP) | VAF 39/145 reads (27%) | catalogued as rs1291516752; called by muse, mutect2
- CFAP20DC | c.1464T>C p.P488= (on ENST00000482387 / NM_001351530.2; = p.P363= on NM_198463.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 47/183 reads (26%) | catalogued as rs1399644104; called by muse, mutect2, varscan2
- CLEC4D | c.63G>T p.S21= | Silent (SNP) | VAF 43/279 reads (15%) | catalogued as COSV100223037; called by muse, mutect2
- CYFIP2 | c.3102A>T p.I1034= (on ENST00000616178 / NM_001291722.2; = p.I1009= on NM_014376.4) | Silent (SNP) | VAF 36/174 reads (21%) | called by muse, mutect2, varscan2
- ENG | c.504C>T p.I168= | Silent (SNP) | VAF 42/229 reads (18%) | called by muse, mutect2, varscan2
- EPHA3 | c.2916A>G p.L972= | Silent (SNP) | VAF 42/215 reads (20%) | called by muse, mutect2, varscan2
- ESPL1 | c.6282C>T p.N2094= | Silent (SNP) | VAF 82/451 reads (18%) | catalogued as rs919628678; called by muse, mutect2, varscan2
- FAM83H | c.360C>T p.T120= | Silent (SNP) | VAF 49/166 reads (30%) | catalogued as rs199503722; called by muse, mutect2, varscan2
- FGF5 | c.349C>T p.L117= | Silent (SNP) | VAF 11/82 reads (13%) | called by muse, mutect2, varscan2
- GOLGA2 | c.2292G>A p.Q764= | Silent (SNP) | VAF 51/251 reads (20%) | catalogued as rs1306453315; called by muse, mutect2, varscan2
- HIVEP2 | c.4551G>T p.S1517= | Silent (SNP) | VAF 74/399 reads (19%) | catalogued as COSV99176378; called by muse, mutect2, varscan2
- HLTF | c.1668G>T p.L556= | Silent (SNP) | VAF 37/325 reads (11%) | called by muse, mutect2, varscan2
- ITGAE | c.1944C>A p.S648= | Silent (SNP) | VAF 60/257 reads (23%) | called by muse, mutect2, varscan2
- MGMT | c.582C>A p.A194= (on ENST00000306010; = p.A163= on NM_002412.5) | Silent (SNP) | VAF 60/315 reads (19%) | called by muse, mutect2, varscan2
- MMP15 | c.1755C>T p.P585= | Silent (SNP) | VAF 31/317 reads (10%) | catalogued as rs769537811; called by muse, mutect2
- MYH15 | c.5655A>G p.L1885= | Silent (SNP) | VAF 42/248 reads (17%) | called by muse, mutect2, varscan2
- NCKAP1 | c.993C>T p.A331= | Silent (SNP) | VAF 55/282 reads (20%) | catalogued as rs760305463, COSV100720063; called by muse, mutect2, varscan2
- NTN1 | c.795G>C p.S265= | Silent (SNP) | VAF 56/238 reads (24%) | called by muse, mutect2, varscan2
- NUTM2A | c.2277C>A p.P759= | Silent (SNP) | VAF 50/214 reads (23%) | called by mutect2, varscan2
- OOEP | c.330C>T p.L110= | Silent (SNP) | VAF 32/132 reads (24%) | catalogued as rs867845596; called by muse, mutect2, varscan2
- OVCH1 | c.2577C>A p.P859= | Silent (SNP) | VAF 70/304 reads (23%) | called by muse, mutect2, varscan2
- PDE11A | c.570C>T p.I190= | Silent (SNP) | VAF 85/410 reads (21%) | catalogued as rs1559062510; called by muse, mutect2, varscan2
- PFKP | c.1287A>T p.V429= | Silent (SNP) | VAF 35/175 reads (20%) | called by muse, mutect2
- PITX3 | c.840C>G p.P280= | Silent (SNP) | VAF 44/210 reads (21%) | called by muse, mutect2, varscan2
- PTPN14 | c.420G>A p.R140= | Silent (SNP) | VAF 50/256 reads (20%) | catalogued as COSV65284254; called by muse, mutect2, varscan2
- RBBP8 | c.1272C>T p.Y424= | Silent (SNP) | VAF 50/277 reads (18%) | catalogued as rs528258071; called by muse, mutect2, varscan2
- STX1B | c.18A>G p.Q6= | Silent (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2, varscan2
- SYNGR1 | c.669C>G p.T223= | Silent (SNP) | VAF 191/431 reads (44%) | catalogued as rs202067842, CM076551; called by muse, mutect2, varscan2
- TRIM67 | c.1158C>T p.Y386= | Silent (SNP) | VAF 64/289 reads (22%) | catalogued as rs772556958, COSV64158537; called by muse, mutect2, varscan2
- TTLL10 | c.1371C>T p.L457= (on ENST00000379289 / NM_001130045.2; = p.L384= on NM_153254.3) | Silent (SNP) | VAF 35/163 reads (21%) | catalogued as rs746534372, COSV64959256; called by muse, mutect2, varscan2
- XPO7 | c.2955G>T p.T985= | Silent (SNP) | VAF 75/173 reads (43%) | catalogued as rs762839424, COSV99380665; called by muse, mutect2, varscan2
- ZAN | c.3363C>A p.P1121= | Silent (SNP) | VAF 60/345 reads (17%) | catalogued as COSV100769777; called by muse, mutect2, varscan2
- ZNF513 | c.906T>A p.T302= | Silent (SNP) | VAF 66/375 reads (18%) | called by muse, mutect2, varscan2
- ZNF556 | c.853A>C p.R285= | Silent (SNP) | VAF 69/394 reads (18%) | called by muse, mutect2, varscan2
- AC107023.1 | n.25+5511G>A | Intron (SNP) | VAF 34/192 reads (18%) | called by muse, mutect2, varscan2
- AC244258.1 | n.822G>A | RNA (SNP) | VAF 60/290 reads (21%) | catalogued as rs1434470462; called by muse, mutect2, varscan2
- ACBD5 | chr10:27195378 G>A | 3'Flank (SNP) | VAF 22/126 reads (17%) | called by muse, mutect2, varscan2
- ADPGK | chr15:72783804 G>C | 5'Flank (SNP) | VAF 13/55 reads (24%) | called by muse, mutect2, varscan2
- ANKZF1 | c.1204+28A>T | Intron (SNP) | VAF 53/280 reads (19%) | called by muse, mutect2, varscan2
- APTX | chr9:32972744 C>T | 3'Flank (SNP) | VAF 28/100 reads (28%) | called by muse, mutect2, varscan2
- ATP10A | c.449+345C>A | Intron (SNP) | VAF 38/183 reads (21%) | called by muse, mutect2, varscan2
- CCDC83 | chr11:85852944 G>T | 5'Flank (SNP) | VAF 7/19 reads (37%) | catalogued as rs1261860863; called by muse, mutect2, varscan2
- CHCHD6 | c.-6C>A | 5'UTR (SNP) | VAF 105/609 reads (17%) | called by muse, mutect2, varscan2
- GLIS3 | c.*2dup | 3'UTR (INS) | VAF 81/399 reads (20%) | called by mutect2, pindel, varscan2
- HMGA2 | c.-17C>T | 5'UTR (SNP) | VAF 48/240 reads (20%) | catalogued as COSV63591387; called by muse, mutect2, varscan2
- IL4R | c.70+855G>T | Intron (SNP) | VAF 27/112 reads (24%) | called by muse, mutect2, varscan2
- KLF6 | c.*72G>A | 3'UTR (SNP) | VAF 91/404 reads (23%) | catalogued as rs1436884354; called by muse, mutect2, varscan2
- KRBOX4 | c.-22C>T | 5'UTR (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2, varscan2
- LINC02843 | n.483C>T | RNA (SNP) | VAF 23/95 reads (24%) | called by muse, mutect2, varscan2
- MOCS1 | chr6:39934527 C>T | 5'Flank (SNP) | VAF 43/204 reads (21%) | catalogued as COSV57934568; called by muse, mutect2, varscan2
- MSL3 | c.-9G>A | 5'UTR (SNP) | VAF 33/72 reads (46%) | catalogued as rs368034828; called by muse, mutect2, varscan2
- QARS1 | c.-24C>G | 5'UTR (SNP) | VAF 22/90 reads (24%) | catalogued as rs755142771, COSV100069870; called by muse, mutect2, varscan2
- RGS11 | c.318+209G>A | Intron (SNP) | VAF 74/319 reads (23%) | called by muse, mutect2, varscan2
- SGK1 | c.285+62G>T | Intron (SNP) | VAF 24/129 reads (19%) | called by muse, mutect2, varscan2
- SHISA8 | chr22:41910505 G>T | 3'Flank (SNP) | VAF 44/84 reads (52%) | called by muse, varscan2
- SLC6A10P | n.3701G>T | RNA (SNP) | VAF 26/123 reads (21%) | called by mutect2, varscan2
- ST7 | c.151+5497A>G | Intron (SNP) | VAF 40/128 reads (31%) | catalogued as rs901268749; called by muse, mutect2, varscan2
- WDR73 | c.518-13G>T | Intron (SNP) | VAF 85/388 reads (22%) | called by muse, mutect2, varscan2
- WT1 | chr11:32438797 G>T | 5'Flank (SNP) | VAF 136/702 reads (19%) | called by muse, mutect2, varscan2
- XPNPEP1 | c.-15del | 5'UTR (DEL) | VAF 49/253 reads (19%) | called by mutect2, pindel, varscan2
- ZNF207 | c.551+520T>C | Intron (SNP) | VAF 12/68 reads (18%) | called by muse, mutect2, varscan2
